Somatic mutation profile of tumor specimen TARGET-20-PAKRZG-04A (aliquot TARGET-20-PAKRZG-04A-02D) from TARGET case TARGET-20-PAKRZG, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.7 years (4,648 days).
Specimen TARGET-20-PAKRZG-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54484fc0-02fe-45dd-b4b1-4d99133b36e6.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PAKRZG-14A (Bone Marrow Normal), aliquot TARGET-20-PAKRZG-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f887cf4d-b678-462d-aa24-dcdfc94ed47e

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 2, Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA3 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM151695, COSV100650850, COSV60518513; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCTTG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 11/36 reads (31%) | catalogued as COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, pindel, varscan2
- WT1 | c.664_665dup p.S223Tfs*69 | Frame Shift Ins (INS) | VAF 38/59 reads (64%) | called by mutect2, pindel, varscan2
- DICER1 | c.5604-13G>T | Intron (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
